Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A2CS, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A2CS-01A (Primary Tumor).

[page 1 of 4]
TORY MEDICINE PROGRAM

Surgical Pathology Consultation Report

Patient Name:		Accession #:	
MRN:		Collected:	
DOB:		Received:	
Gender: F	Service:	Reported:	
HCN:	Visit #:		
Ordering MD:	Location:		
Copy To:	Facility:		

ICD-0-3
Carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9 lw 6/18/14

Specimen(s) Received

1. Lymph-Node: Apical node right posterior triangle
2. Neck :Content right Neck double stitch marks apex + single stitch marks posterior
3. Neck :Apex Right posterior triangle
4. Neck :Left neck content stitch marked apex double superior single posterior
5. Surgical Waste
6. Trachea :Right paratracheal node
7. Thyroid :Total Thyroid stitch marks upper pole left lobe

Diagnosis

1. Metastatic papillary thyroid carcinoma: Lymph node, 1 (apical node, right posterior triangle) biopsy.
2. Metastatic papillary thyroid carcinoma: Lymph nodes, 8 of 10 (neck, right) dissection specimen.
3. No pathological diagnosis: Lymph node, 1 (neck, right posterior triangle) biopsy.
4. Metastatic papillary thyroid carcinoma with extranodal extension: Lymph nodes, 10 of 17 (neck, left) dissection specimen.
5. Metastatic papillary thyroid carcinoma: Lymph node, 1 of 3 (site not specified, listed as "surgical waste") biopsy.
6. Metastatic papillary thyroid carcinoma with extranodal extension: Lymph nodes, 3 of 4 (right paratracheal) biopsy.
7. Widely invasive papillary carcinoma, classic variant, 6.3 cm, replacing entire thyroid and involving resection margins: Thyroid
Metastatic papillary thyroid carcinoma with extranodal extension: Lymph nodes, 11 of 12
No pathological diagnosis: Parathyroid (inferior/central compartment)
No pathological diagnosis: Thymus
-Total thyroidectomy specimen. See Comment.

[page 2 of 4]
Synoptic Data

Procedure:	Total thyroidectomy with central compartment dissection Total thyroidectomy with bilateral neck dissection
Received:	Fresh
Specimen Integrity:	Intact
Specimen Size:	Right lobe: 3.6 cm 2.5 cm 1.3 cm Left lobe: 3.4 cm 2.3 cm 0.9 cm Isthmus +/- pyramidal lobe: 3.5 cm 1.5 cm 0.5 cm Central compartment: 5.5 cm 4.0 cm 1.1 cm Right neck dissection: 14.0 cm 6.0 cm 1.3 cm Left neck dissection: 10.5 cm 5.0 cm 1.4 cm
Specimen Weight:	24.3 g
Tumor Focality:	Unifocal
----- DOMINANT TUMOR -----	
Tumor Laterality:	Right lobe Left lobe Isthmus
Tumor Size:	Greatest dimension: 6.3cm Additional dimension: 3.6 cm Additional dimension: 1.3 cm
Histologic Type:	Papillary carcinoma, classical (usual) Papillary carcinoma, clear cell variant Classical (papillary) architecture Diffuse sclerosing architecture Classical cytomorphology
Histologic Grade:	Not applicable
Margins:	Margin(s) involved by carcinoma
Tumor Capsule:	None
Tumor Capsular Invasion:	Present, extent widely invasive
Lymph-Vascular Invasion:	Present, focal extent (less than 4 vessels)
Perineural Invasion:	Indeterminate
Extrathyroidal Extension:	Cannot be assessed
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT3: Tumor more than 4 cm, limited to thyroid or with minimal extrathyroidal extension (eg, extension to sternothyroid muscle or perithyroid soft tissues)

[page 3 of 4]
Regional Lymph Nodes (pN): pN1b: Metastases to unilateral, bilateral or contralateral
cervical or superior mediastinal lymph nodes
Number of regional lymph nodes examined: 49
Number of regional lymph nodes involved: 35
Lymph Node, Extranodal Extension Present
Distant Metastasis (pM): Not applicable
Additional Pathologic Findings: Parathyroid gland(s), within normal limits

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Comment

This tumor replaces the entire thyroid gland in an infiltrative pattern. The diffuse nature of this tumor is reminiscent of the diffuse sclerosing variant, but in this case the abundant fibrosis, psammoma bodies and chronic inflammation that characterize that variant are not seen. The tumor extends to the painted margins of resection in right and left lobes and in the isthmus. There is unequivocal lymphatic invasion, and regions suspicious for, but not diagnostic of angioinvasion are seen.

This report has been amended to add the lymph node involvement from a previous specimen (). In addition, since the resection margins are involved by tumor and no extrathyroidal tissue is included in the specimen, evaluation of extrathyroidal extension cannot be performed on this specimen. Intraoperative findings may alter the stage of the primary tumor.

verified by:

Electronically

Clinical History

papillary Ca Thyroid

Gross Description

1. The specimen labeled with the patient's name and as "Lymph Node: Apical node right posterior triangle" consists of a piece of tan-brown tissue measuring 1.4 x 0.5 x 0.5 cm.
1A bisected and submitted in toto.

2. The specimen labeled with the patient's name and as "Neck: Content right neck double stitch marks apex + single stitch marks posterior" consists of a piece of fibroadipose tissue that is oriented with two stitches and measures 14.0 x 6.0 x 1.3 cm and contains multiple lymph nodes that range from 0.5 x 0.3 x 0.3 cm to 1.7 x 1.2 x 1.1 cm. One piece of the largest nodule is stored frozen. The lymph nodes are submitted in toto from apex to base as follows:

- 2A two lymph nodes.
- 2B one lymph node bisected.
- 2C one lymph node bisected.
- 2D 3 lymph nodes
- 2E remainder of the largest lymph node.
- 2F one lymph node bisected.

3. The specimen labeled with the patient's name and as "Neck: Apex right posterior triangle" consists of a piece of yellow-brown tissue measuring in 1.8 x 1.2 x 0.8 cm.

3A bisected and submitted in toto.

[page 4 of 4]
4. The specimen labeled with the patient's name and as "Neck: Left neck content stitch marked apex double superior single posterior" consists of a piece of fibroadipose tissue that is oriented with two stitches and measures 10.5 x 5.0 x 1.4 cm and contains multiple lymph nodes that range from 0.5 x 0.3 x 0.3 cm to 2.3 x 1.2 x 0.7 cm. The lymph nodes are submitted in toto from apex to base as follows:

- 4A two lymph nodes.
- 4B 3 lymph nodes.
- 4C two lymph nodes
- 4D one lymph node bisected.
- 4E one lymph node bisected
- 4F one lymph node bisected.
- 4G two lymph nodes
- 4H one lymph node bisected
- 4I two lymph nodes.

5. The specimen labeled with the patient's name and as "Surgical Waste" consists of two pieces of fatty tissue measuring 1.7 x 1.0 x 0.8 cm in 2.5 x 1.0 x 0.8 cm. Within the fatty tissue one lymph node is identified measuring 1.4 x 0.7 x 0.7 cm.

5A representative sections submitted

6. The specimen labeled with the patient's name and as "Trachea: Right paratracheal node" consists of 3 pieces of pale tan tissue measuring from 0.8 x 0.8 x 0.6 cm to 2.5 x 1.1 x 1.0 cm.
6A-B submitted in toto.

7. The specimen labeled with the patient's name and as "Thyroid: Total thyroid stitch marks upper pole left lobe" consists of a thyroid gland that is oriented with a stitch and weighs 24.3 g. The right lobe measures 3.6 cm SI x 2.5 cm ML x 1.3 cm AP, the left lobe measures 3.4 cm SI x 2.3 cm ML x 0.9 cm AP and the isthmus measures 3.5 cm SI x 1.5 cm ML x 0.5 cm AP. The external surfaces have fibrous adhesions. There is a piece of fatty tissue attached on the inferior aspect of the thyroid measuring 5.5 cm SI x 4.0 cm ML x 1.1 cm AP. No parathyroid glands are identified. Multiple lymph nodes are identified from the soft tissue attached to the inferior aspect of the thyroid; they measure from 0.7 cm to 2.0 cm. The external surface is painted with silver nitrate. The upper and lower pole of the right and left lobe contain multiple delineated nodules; the largest nodule in the left lobe superior pole measures 1.6 cm SI x 0.8 cm ML x 0.6 cm AP. The remainder of the thyroid tissue is unremarkable. Sections of larger nodules and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

- 7A-F right lobe, superior to inferior
- 7G-H isthmus
- 7I-L left lobe, superior to inferior
- 7M two lymph nodes
- 7N two lymph nodes
- 7O one lymph node bisected
- 7P-Q one lymph node serially sectioned
- 7R-T remainder of the fatty tissue.
-

Source: NCI Genomic Data Commons file b30374a9-580d-4504-86c3-3a48c9d20899 (TCGA-EM-A2CS.4BCF51D2-6278-4C59-9CFD-BE686A00F7ED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).